Somatic mutation profile of tumor specimen TCGA-06-0184-01A (aliquot TCGA-06-0184-01A-01D-1491-08) from TCGA case TCGA-06-0184, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.8 years (23,317 days).
Specimen TCGA-06-0184-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e665149-e2b4-4ef1-a336-b7062787e704.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0184-10B (Blood Derived Normal), aliquot TCGA-06-0184-10B-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aabb9bae-83c0-4076-948f-ff5f4631af58

The open-access MAF lists 58 somatic variants for this specimen: 43 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 14, Nonsense Mutation 6, Frame Shift Del 3, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554893792, COSV64290842, COSV64296487, COSV64301821; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 39/107 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs780005218, COSV61256390; called by muse, mutect2, varscan2
- ANGPT4 | c.1103A>T p.H368L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV67920982; called by muse, mutect2, varscan2
- BSN | c.6020G>A p.G2007D | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs764776662, COSV56514595; called by muse, mutect2, varscan2
- BTK | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 107/189 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as CM1513064, COSV58118120; called by muse, mutect2, varscan2
- C12orf50 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 89/230 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as rs769559699, COSV53894077; called by muse, mutect2, varscan2
- CADPS | c.34G>C p.D12H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as COSV51882132; called by muse, mutect2, varscan2
- CCDC66 | c.2099G>A p.R700K (on ENST00000394672 / NM_001353147.1; = p.R666K on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV58302258; called by muse, mutect2, varscan2
- CD22 | c.2059C>T p.R687* | Nonsense Mutation (SNP) | VAF 67/346 reads (19%) | catalogued as rs758916954, COSV50050362; called by muse, varscan2
- CDH18 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs868527442, COSV56907663, COSV56951940; called by muse, mutect2, varscan2
- CES1 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as rs200227274, COSV100828676, COSV62087220; called by muse, mutect2, varscan2
- CHGB | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as rs553869356, COSV66759863; called by muse, mutect2, varscan2
- CHP2 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 20/92 reads (22%) | catalogued as COSV55649376; called by muse, mutect2, varscan2
- CNTN3 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs745699942, COSV55165800; called by muse, mutect2, varscan2
- CUL1 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 98/321 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV57387487; called by muse, mutect2, varscan2
- DSTYK | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV65686698; called by muse, mutect2
- FFAR4 | c.871A>C p.I291L | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV65160290; called by muse, mutect2
- GNAT3 | c.942del p.E315Kfs*9 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as rs748562154; called by mutect2, pindel, varscan2
- GPR161 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 38/127 reads (30%) | catalogued as rs961642617, COSV54788550; called by muse, mutect2, varscan2
- GPR45 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); catalogued as rs1352198171, COSV51523131; called by muse, mutect2, varscan2
- LARP1B | c.166G>C p.G56R | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); catalogued as COSV52798079; called by muse, mutect2, varscan2
- LTN1 | c.577-1G>A p.X193_splice | Splice Site (SNP) | VAF 37/141 reads (26%) | catalogued as COSV63733271; called by muse, mutect2, varscan2
- MADD | c.4583G>A p.R1528H | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs568759986, COSV60621635; called by muse, mutect2, varscan2
- MATR3 | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV63076411; called by muse, mutect2, varscan2
- MCM2 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as COSV54032581; called by muse, mutect2, varscan2
- MUC2 | c.2047G>A p.D683N | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.36); catalogued as rs753506402; called by muse, mutect2, varscan2
- NADSYN1 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV59810916; called by muse, mutect2, varscan2
- NF1 | c.6906del p.Q2302Hfs*17 (on ENST00000358273 / NM_001042492.3; = p.Q2281Hfs*17 on NM_000267.3) | Frame Shift Del (DEL) | VAF 39/143 reads (27%) | catalogued as COSV62196682; called by mutect2, pindel, varscan2
- NFX1 | c.365A>C p.Q122P | Missense Mutation (SNP) | VAF 83/297 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.69); catalogued as COSV59308903; called by muse, mutect2, varscan2
- PCDH18 | c.2851G>C p.G951R | Missense Mutation (SNP) | VAF 87/353 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61267051, COSV61270663; called by muse, mutect2, varscan2
- PCDHGC3 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV52746662; called by muse, mutect2, varscan2
- PDZRN3 | c.22T>C p.F8L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV55201901; called by muse, mutect2
- PROX2 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as COSV71519992; called by muse, mutect2, varscan2
- REV3L | c.2696T>A p.F899Y | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.419); catalogued as COSV62616785; called by muse, mutect2, varscan2
- RUFY3 | c.854T>A p.V285E | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56912031; called by muse, mutect2, varscan2
- SEMA6B | c.515C>G p.A172G | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56704057; called by muse, mutect2, varscan2
- SPSB1 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 90/235 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV60162341; called by muse, mutect2, varscan2
- TEK | c.3317C>T p.T1106M | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751768682, COSV66228046; called by muse, mutect2, varscan2
- TPTE2 | c.529C>T p.R177* (on ENST00000400230 / NM_199254.2; = p.R100* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as rs538397448, COSV55016766, COSV55028827; called by muse, mutect2, varscan2
- ZC3H13 | c.2525G>A p.R842H | Missense Mutation (SNP) | VAF 89/301 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as rs144621814; called by muse, mutect2, varscan2
- ZDBF2 | c.5795G>A p.R1932H | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs763186071, COSV65621705, COSV65623112; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IRF2BP2 | c.956_957del p.G319Afs*7 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- BSN | c.5007T>C p.R1669= | Silent (SNP) | VAF 35/113 reads (31%) | catalogued as COSV56514588; called by muse, mutect2, varscan2
- CNTLN | c.186G>A p.G62= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV52070051; called by muse, mutect2, varscan2
- DNAH11 | c.5175C>T p.Y1725= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs747361665, COSV60958101; called by muse, mutect2, varscan2
- EBF1 | c.1290C>T p.H430= | Silent (SNP) | VAF 52/167 reads (31%) | catalogued as rs570120838, COSV58171050; called by muse, mutect2, varscan2
- FGD2 | c.1542C>T p.Y514= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as rs756823723, COSV51462678; called by muse, mutect2, varscan2
- ISLR | c.396C>T p.N132= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as rs769729461, COSV51433044; called by muse, mutect2, varscan2
- ITGA4 | c.1518C>T p.G506= | Silent (SNP) | VAF 68/292 reads (23%) | catalogued as rs200212723, COSV51998674; called by muse, mutect2, varscan2
- KCNK10 | c.123G>A p.P41= | Silent (SNP) | VAF 46/220 reads (21%) | catalogued as rs867074103, COSV56640940, COSV56642195; called by muse, mutect2, varscan2
- MS4A7 | c.117C>T p.N39= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as rs767560560, COSV55729105; called by muse, mutect2, varscan2
- SPATA19 | c.225C>T p.S75= | Silent (SNP) | VAF 8/175 reads (5%) | catalogued as COSV54483476; called by muse, mutect2
- SYNE2 | c.6852G>A p.A2284= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs1224935689, COSV59943530; called by muse, mutect2, varscan2
- THRB | c.144G>A p.T48= | Silent (SNP) | VAF 65/259 reads (25%) | catalogued as rs138865141; called by muse, mutect2, varscan2
- TRIM58 | c.489C>T p.N163= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as rs758519275, COSV63569464; called by muse, mutect2, varscan2
- ZAN | c.4635G>T p.S1545= | Silent (SNP) | VAF 63/459 reads (14%) | catalogued as COSV61809876; called by muse, mutect2, varscan2
- ZNF766 | c.19-225A>T | Intron (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100765262; called by muse, mutect2, varscan2
